Somatic mutation profile of tumor specimen MMRF_1922_1_BM_CD138pos (aliquot MMRF_1922_1_BM_CD138pos_T1_KBS5U_L06430) from MMRF case MMRF_1922, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.5 years (21,374 days).
Specimen MMRF_1922_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 793d8d8f-e02b-4343-bd22-b0aff664a372.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1922_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1922_1_PB_Whole_C3_KBS5U_L06475; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/724b9c79-26fd-4570-a977-2467da964855

The open-access MAF lists 124 somatic variants for this specimen: 52 protein-altering or splice-affecting, 11 silent, 61 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, 3'UTR 43, Silent 11, 5'Flank 6, Intron 5, 5'UTR 4, Nonsense Mutation 3, RNA 2, 3'Flank 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 126/265 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CCDC62 | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.172); catalogued as rs985198794; called by muse, mutect2, varscan2
- EEF1A2 | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); catalogued as COSV99419807; called by muse, mutect2, varscan2
- FREM1 | c.3777G>T p.K1259N | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.258); catalogued as COSV101084452; called by muse, mutect2
- GAD1 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs201233553, COSV60151912; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HNRNPCL3 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.093); catalogued as rs1188292918; called by muse, mutect2, varscan2
- IGHV2-70 | c.286A>G p.K96E | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.351); catalogued as rs184904469; called by muse, varscan2
- IGLV1-44 | c.265A>T p.T89S | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as rs572589957; called by muse, mutect2, varscan2
- IGLV3-25 | c.332G>A p.S111N | Missense Mutation (SNP) | VAF 46/62 reads (74%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs537761116; called by muse, mutect2, varscan2
- IGLV7-46 | c.318G>C p.E106D | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs112695317; called by muse, mutect2, varscan2
- IMP4 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1470977298; called by muse, mutect2, varscan2
- IRF2BP1 | c.751G>A p.G251R | Missense Mutation (SNP) | VAF 55/151 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.717); catalogued as COSV56192947; called by muse, mutect2, varscan2
- KANSL1L | c.848G>T p.G283V | Missense Mutation (SNP) | VAF 28/188 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV55998245; called by muse, mutect2, varscan2
- MGAT5B | c.1547C>T p.P516L (on ENST00000569840 / NM_001199172.2; = p.P514L on NM_144677.3) | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs566357260, COSV56927640; called by muse, mutect2, varscan2
- MUC17 | c.8237C>T p.P2746L | Missense Mutation (SNP) | VAF 24/288 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.908); catalogued as rs776108951; called by muse, mutect2
- PCDHA6 | c.1169C>T p.T390M | Missense Mutation (SNP) | VAF 26/214 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.125); catalogued as COSV67047023; called by muse, mutect2, varscan2
- PLCH1 | c.1636C>T p.R546* (on ENST00000340059 / NM_001130960.2; = p.R558* on NM_014996.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 14/33 reads (42%) | catalogued as rs142222970; called by muse, mutect2, varscan2
- PLEKHO2 | c.775G>T p.E259* | Nonsense Mutation (SNP) | VAF 52/220 reads (24%) | catalogued as COSV60261529, COSV60262962; called by muse, mutect2, varscan2
- PSKH1 | c.1073T>C p.M358T | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT tolerated (0.58); PolyPhen benign (0.011); catalogued as rs1567402817; called by muse, mutect2, varscan2
- PUS7L | c.1783G>C p.V595L | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.381); catalogued as COSV100786445; called by muse, mutect2
- RPS4X | c.659C>G p.T220S | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV100289162; called by muse, mutect2, varscan2
- SI | c.5354T>C p.V1785A | Missense Mutation (SNP) | VAF 108/177 reads (61%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as rs370958579; called by muse, mutect2, varscan2
- SIN3B | c.3407C>T p.T1136M | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs150206415; called by muse, mutect2, varscan2
- SLC5A2 | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1199653474; called by muse, mutect2, varscan2
- SYDE1 | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as rs560670595; called by muse, mutect2, varscan2
- TACR3 | c.1289C>T p.T430M | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.068); catalogued as rs200736098, COSV59200720; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TBK1 | c.188A>G p.N63S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs565166649; called by muse, mutect2, varscan2
- ABCA9 | c.2569T>G p.L857V | Missense Mutation (SNP) | VAF 118/123 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- AC100868.1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- ANKRD17 | c.5626G>T p.G1876C | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- BACH2 | c.1713G>A p.M571I | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.9); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BAG3 | c.452G>T p.C151F | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- C2 | c.899C>G p.S300* | Nonsense Mutation (SNP) | VAF 5/74 reads (7%) | called by muse, mutect2
- DIS3L2 | c.2411C>G p.S804C | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- DSE | c.470G>T p.G157V | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAT4 | c.6007C>A p.L2003I | Missense Mutation (SNP) | VAF 54/105 reads (51%) | SIFT tolerated (0.35); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- GPR149 | c.189C>A p.N63K | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- GPRC6A | c.2311T>C p.F771L | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- IRX6 | c.751C>A p.L251I | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.227); called by muse, varscan2
- IYD | c.56T>A p.I19N | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- KLF14 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LRRC15 | c.1316T>A p.L439Q | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MTUS2 | c.1304G>C p.S435T | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MYO3B | c.1685C>T p.A562V | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- NCOR2 | c.1383+1G>T p.X461_splice | Splice Site (SNP) | VAF 13/77 reads (17%) | called by muse, mutect2
- OR4C16 | c.188A>G p.Y63C | Missense Mutation (SNP) | VAF 76/246 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- PIWIL2 | c.2834A>C p.K945T | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- PRAMEF20 | c.633A>C p.E211D | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- PTK2 | c.1514G>A p.G505E | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by mutect2, varscan2
- TBX3 | c.1402G>C p.E468Q (on ENST00000257566 / NM_016569.4; = p.E448Q on NM_005996.4) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- TNFAIP8L3 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2
- ZBTB7A | c.769_772del p.F257Rfs*66 | Frame Shift Del (DEL) | VAF 9/57 reads (16%) | called by mutect2, pindel, varscan2
- AKAP13 | c.600G>T p.G200= | Silent (SNP) | VAF 11/182 reads (6%) | called by muse, mutect2
- ATP5F1B | c.105C>A p.A35= | Silent (SNP) | VAF 13/77 reads (17%) | called by muse, mutect2, varscan2
- CLTC | c.4722C>T p.Y1574= | Silent (SNP) | VAF 18/129 reads (14%) | catalogued as rs367867382; called by muse, mutect2, varscan2
- FABP6 | c.78C>T p.S26= | Silent (SNP) | VAF 14/134 reads (10%) | catalogued as rs761500860; called by muse, mutect2, varscan2
- IGLV1-40 | c.66G>T p.V22= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs368418521; called by muse, mutect2, varscan2
- MYL3 | c.75T>C p.P25= | Silent (SNP) | VAF 5/86 reads (6%) | catalogued as COSV52767767; called by muse, mutect2
- PPM1L | c.81C>T p.F27= | Silent (SNP) | VAF 17/131 reads (13%) | called by muse, mutect2, varscan2
- SERINC2 | c.819C>A p.V273= (on ENST00000373709 / NM_178865.5; = p.V277= on NM_018565.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 33/71 reads (46%) | called by muse, mutect2, varscan2
- TMEM67 | c.780C>T p.Y260= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as rs966581270, COSV60044284; called by muse, mutect2
- TTC1 | c.355C>T p.L119= | Silent (SNP) | VAF 24/240 reads (10%) | catalogued as rs900057842; called by muse, varscan2
- ZNF175 | c.1431C>T p.C477= | Silent (SNP) | VAF 45/70 reads (64%) | called by muse, mutect2, varscan2
- ABCA11P | n.1287T>C | RNA (SNP) | VAF 18/86 reads (21%) | called by muse, mutect2, varscan2
- AL441992.2 | c.*5269A>G | 3'UTR (SNP) | VAF 10/18 reads (56%) | called by muse, mutect2, varscan2
- ALKAL2 | c.*456A>G | 3'UTR (SNP) | VAF 28/82 reads (34%) | catalogued as rs1385273534; called by muse, mutect2
- ANK1 | c.*1969C>T | 3'UTR (SNP) | VAF 16/30 reads (53%) | called by muse, mutect2, varscan2
- ANKRD18A | chr9:38622899 ins T | 5'Flank (INS) | VAF 11/102 reads (11%) | called by mutect2, pindel, varscan2
- ANO9 | c.-24G>A | 5'UTR (SNP) | VAF 20/67 reads (30%) | called by muse, varscan2
- AP000769.3 | chr11:65504266 T>G | 5'Flank (SNP) | VAF 34/155 reads (22%) | called by muse, mutect2, varscan2
- CAMK4 | c.*4304_*4309dup | 3'UTR (INS) | VAF 20/106 reads (19%) | called by mutect2, varscan2
- CDX1 | c.*419C>T | 3'UTR (SNP) | VAF 57/87 reads (66%) | called by muse, mutect2, varscan2
- CFAP92 | c.*250C>T | 3'UTR (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- CNOT7 | c.729+451C>A | Intron (SNP) | VAF 5/35 reads (14%) | catalogued as rs1327785782; called by muse, mutect2, varscan2
- DOK7 | c.*628C>T | 3'UTR (SNP) | VAF 31/68 reads (46%) | catalogued as rs11542616; called by muse, mutect2, varscan2
- DTWD1 | c.*492A>G | 3'UTR (SNP) | VAF 6/128 reads (5%) | called by muse, mutect2
- EEF1A1 | c.*956A>G | 3'UTR (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2, varscan2
- ELAVL2 | chr9:23691316 G>T | 3'Flank (SNP) | VAF 76/118 reads (64%) | called by muse, mutect2, varscan2
- FDPS | c.773+12T>G | Intron (SNP) | VAF 78/146 reads (53%) | called by muse, mutect2, varscan2
- GATAD2A | c.*2833C>T | 3'UTR (SNP) | VAF 65/100 reads (65%) | called by muse, mutect2, varscan2
- GLDN | c.*2486T>C | 3'UTR (SNP) | VAF 15/124 reads (12%) | called by muse, mutect2, varscan2
- HOXA6 | chr7:27151573 A>C | 5'Flank (SNP) | VAF 58/190 reads (31%) | called by muse, mutect2, varscan2
- IGLV1-41 | n.150C>G | RNA (SNP) | VAF 26/52 reads (50%) | catalogued as rs1439802174; called by muse, mutect2, varscan2
- ITPK1 | c.-117C>G | 5'UTR (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- KIRREL1 | c.*3697G>A | 3'UTR (SNP) | VAF 10/31 reads (32%) | catalogued as rs1267533023; called by muse, mutect2, varscan2
- LY75 | c.*873A>G | 3'UTR (SNP) | VAF 18/50 reads (36%) | called by muse, mutect2, varscan2
- MIS12 | c.*1310C>T | 3'UTR (SNP) | VAF 11/65 reads (17%) | called by muse, mutect2, varscan2
- MOSPD1 | c.*346G>A | 3'UTR (SNP) | VAF 21/38 reads (55%) | called by muse, mutect2, varscan2
- MYCBP2 | c.*238del | 3'UTR (DEL) | VAF 15/33 reads (45%) | called by mutect2, pindel, varscan2
- MYO6 | c.*746A>C | 3'UTR (SNP) | VAF 50/76 reads (66%) | called by muse, mutect2, varscan2
- NAA60 | c.-7+134C>T | Intron (SNP) | VAF 5/15 reads (33%) | catalogued as rs796914663; called by muse, mutect2
- NKX6-1 | c.*295G>A | 3'UTR (SNP) | VAF 41/82 reads (50%) | called by muse, mutect2, varscan2
- NR1H4 | c.109+2086C>A | Intron (SNP) | VAF 38/40 reads (95%) | called by muse, mutect2, varscan2
- NSUN2 | chr5:6633235 C>T | 5'Flank (SNP) | VAF 15/161 reads (9%) | called by muse, mutect2
- NUS1 | c.*3227T>A | 3'UTR (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2, varscan2
- OR56B1 | c.*54A>T | 3'UTR (SNP) | VAF 35/198 reads (18%) | called by muse, mutect2, varscan2
- PCDH15 | c.*832C>T | 3'UTR (SNP) | VAF 22/87 reads (25%) | catalogued as rs373625431; called by muse, mutect2, varscan2
- PLEKHG6 | c.*149G>T | 3'UTR (SNP) | VAF 34/176 reads (19%) | called by muse, mutect2, varscan2
- PLPP5 | c.184-81T>A | Intron (SNP) | VAF 8/61 reads (13%) | called by muse, mutect2, varscan2
- POLR3B | c.*588C>T | 3'UTR (SNP) | VAF 7/60 reads (12%) | called by muse, mutect2, varscan2
- PTPN13 | c.*157T>C | 3'UTR (SNP) | VAF 12/61 reads (20%) | catalogued as rs931049126; called by muse, mutect2, varscan2
- PXDC1 | c.*556G>T | 3'UTR (SNP) | VAF 12/109 reads (11%) | called by muse, mutect2, varscan2
- RAD51C | chr17:58692594 G>C | 5'Flank (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- RALGAPA2 | c.*1659A>T | 3'UTR (SNP) | VAF 16/67 reads (24%) | called by muse, mutect2, varscan2
- RBM12B | c.*2596A>G | 3'UTR (SNP) | VAF 14/40 reads (35%) | catalogued as rs969687268; called by mutect2, varscan2
- RIC1 | c.*2266T>C | 3'UTR (SNP) | VAF 48/77 reads (62%) | called by muse, mutect2, varscan2
- RND3 | c.-115C>A | 5'UTR (SNP) | VAF 7/45 reads (16%) | called by muse, mutect2, varscan2
- RORB | c.*71G>A | 3'UTR (SNP) | VAF 19/166 reads (11%) | called by muse, mutect2, varscan2
- SEC14L2 | c.*1963G>T | 3'UTR (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2, varscan2
- SEMA5A | c.*4275C>G | 3'UTR (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- SLC26A7 | c.*1333G>T | 3'UTR (SNP) | VAF 10/55 reads (18%) | called by muse, mutect2, varscan2
- SLC2A5 | c.*195C>T | 3'UTR (SNP) | VAF 23/55 reads (42%) | called by muse, mutect2, varscan2
- SLC6A5 | c.*260dup | 3'UTR (INS) | VAF 31/120 reads (26%) | called by mutect2, pindel, varscan2
- SMOC2 | c.*1015G>A | 3'UTR (SNP) | VAF 37/75 reads (49%) | called by muse, mutect2, varscan2
- SOD2 | c.*637G>T | 3'UTR (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2, varscan2
- SPOPL | c.*2515A>G | 3'UTR (SNP) | VAF 10/51 reads (20%) | called by muse, mutect2, varscan2
- SVIP | c.*2907G>C | 3'UTR (SNP) | VAF 4/98 reads (4%) | called by muse, mutect2
- TIGD6 | c.*22A>C | 3'UTR (SNP) | VAF 28/58 reads (48%) | called by muse, mutect2, varscan2
- TMEM151B | c.*99C>T | 3'UTR (SNP) | VAF 22/64 reads (34%) | called by muse, mutect2, varscan2
- TNKS | c.*4820C>T | 3'UTR (SNP) | VAF 16/67 reads (24%) | called by muse, mutect2, varscan2
- TNS3 | c.-144T>G | 5'UTR (SNP) | VAF 15/67 reads (22%) | catalogued as COSV60788150; called by muse, mutect2, varscan2
- TPP1 | c.*1125A>G | 3'UTR (SNP) | VAF 6/62 reads (10%) | catalogued as rs963244886; called by muse, mutect2
- XPNPEP3 | c.*5308C>T | 3'UTR (SNP) | VAF 15/34 reads (44%) | called by muse, mutect2, varscan2
- ZNF578 | chr19:52451444 G>A | 5'Flank (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
